Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACM9, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACM9-TTP1-A (Primary Tumor).

Submissions:

A) removal of lung lobe

Macroscopic Description**Finding:**

- 1) bronchial resection margin
- 2) vascular resection margin
- 3) hilar lymph nodes
- 4) neoplasm
- 5) parenchyma Remote

*TSS verified (L) lung.*UUID:4103F0F8-1A41-4489-A953-802EA8838F18
CDDP-YP-ACM9-01-PR

Lung lobe of cm 18x12x6. To the cut to three centimeters from the edge of the bronchial resection margin finding neoplasia of the maximum diameter of cm 3.7, of necrotic and anthracosis aspect, retracting the pleura. Remaining parenchyma appearance diffusely congested and edematous.

Macroscopic report and diagnosis:

Poorly differentiated adenocarcinoma of the lung G3, with areas of squamous metaplasia and areas of necrosis, retracting but not infiltrating the visceral pleura (4).

Free from neoplastic infiltration of the bronchial (1) and vascular (2) resection margins.

Remaining lung parenchyma place of emphysema, areas of atelectasis and diffuse congestion of vessels(5).

Reactive non specific lymphadenitis with anthracosis into the 5 isolated hilum lymph nodes.

Istological diagnosis: lung adenocarcinoma G3 pT2 N0 Mx

ICB-0-3

adenocarcinoma, NOS 8140/3
Site: (L) lung, NOS C34.9

ICB-10

C34.92

fw
12/16/16

Source: NCI Genomic Data Commons file 1084d173-0d66-4d8a-bc2f-e2eb212e1298 (CDDP-ACM9-TTP1.4103F0F8-1A41-4489-A953-802EA8838F18.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).